Gene-level copy-number profile of tumor specimen SM-JU34I from CPTAC case C827913, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Temporal lobe; Tumor grade: G4.
Specimen SM-JU34I: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5719d06b-d06e-4fd4-9401-748f0a010be3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator 1105217 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/f9afd90b-0f62-421e-8b99-ea3a3a6592de

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 9,038; copy number 2: 49,822; copy number 3: 41.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,966,929–21,967,751, 1 gene (within-gene range 0–1): CDKN2A-DT.
- chr9:23,500,691–23,672,387, 1 gene (within-gene range 0–1): AL445623.2.
- chr9:23,671,788–23,682,662, 2 genes: AL445623.1, NOP56P2.
- chr9:24,905,469–24,905,735, 1 gene: RMRPP5.
- chr9:25,676,389–25,844,585, 2 genes: TUSC1, LINC01241.
- chr9:26,746,953–26,805,862, 3 genes: AL451137.2, AL451137.1, AL356133.1.
- chr22:18,533,646–18,577,968, 1 gene: PI4KAP1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 6,182. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
